Gene-level copy-number profile of tumor specimen TCGA-DX-A1KW-01A from TCGA case TCGA-DX-A1KW, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 67.5 years (24,647 days).
Specimen TCGA-DX-A1KW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.1eb75a8e-2315-43ee-b91c-a55d298524b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1KW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6bf1722c-a189-49f5-bd59-298cbc211b14

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 2: 16,805; copy number 3: 19,087; copy number 4: 18,286; copy number 5: 2,758; copy number 6: 2,059; copy number 7: 2; copy number 8: 98; copy number 9: 160; copy number 10: 71; copy number 11: 33; copy number 12: 45; copy number 14: 1; copy number 17: 65; copy number 18: 10; copy number 19: 8; copy number 21: 1; copy number 22: 27; copy number 24: 28; copy number 27: 6; copy number 28: 26; copy number 31: 40; copy number 33: 26; copy number 34: 9; copy number 38: 23; copy number 39: 13; copy number 40: 38; copy number 41: 3; copy number 43: 18; copy number 45: 2; copy number 51: 1; copy number 54: 13; copy number 55: 5; copy number 58: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1KW-01A-22D-A24M-01): tumor purity 0.83, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:1,957,589–2,081,097, 4 genes: AL355597.1, LINC00700, AL441943.1, MIR6072.
- chr10:9,721,963–9,724,416, 1 gene: HSP90AB7P.
- chr11:55,714,799–55,828,154, 9 genes: OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 797 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,295,068, 47 genes, copy number 10: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:1,931,058–5,694,742, 45 genes, copy number 10–17: AC126768.3, AC124852.1, AC126768.1, AC126768.2, Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1.
- chr5:6,582,136–6,757,044, 5 genes, copy number 12 (within-gene range 6–12): LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A.
- chr5:10,564,070–29,396,095, 213 genes, copy number 8–12 (broad region; genes not listed).
- chr5:38,845,858–43,192,021, 69 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr12:48,327,942–48,628,836, 20 genes, copy number 38: AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P, ANP32D, C12orf54, AC089987.2, RPS10P20, AC089987.1, OR8S1, OR5BS1P, LALBA, OR11M1P.
- chr12:48,654,382–48,656,782, 3 genes, copy number 38: SNORA2C, MIR1291, SNORA2A.
- chr12:49,568,218–49,708,165, 8 genes, copy number 11: PRPF40B, AC020612.3, FAM186B, RNU6-834P, POLR2KP1, AC020612.1, HIGD1AP9, FMNL3.
- chr12:49,709,237–49,709,336, 1 gene, copy number 11: AC020612.2.
- chr12:50,504,985–50,748,657, 4 genes, copy number 40: DIP2B, RNU6-769P, RNU6-238P, Y_RNA.
- chr12:51,809,705–51,891,727, 7 genes, copy number 17: AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33.
- chr12:52,377,812–52,849,092, 34 genes, copy number 17 (within-gene range 2–17): KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78.
- chr12:57,693,955–58,813,060, 34 genes, copy number 40 (within-gene range 2–40): OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:61,231,159–61,232,937, 1 gene, copy number 14: AC090017.1.
- chr12:62,021,570–62,145,643, 2 genes, copy number 12: RPS3P6, AC078789.1.
- chr12:64,622,509–67,978,387, 68 genes, copy number 8–34 (within-gene range 3–34) (broad region; genes not listed).
- chr12:68,001,394–68,036,853, 2 genes, copy number 18: RPL39P28, HNRNPA1P70.
- chr12:68,674,371–70,920,738, 50 genes, copy number 28–54: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr12:73,648,666–74,402,600, 5 genes, copy number 8–27 (within-gene range 2–27): AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882.
- chr12:74,170,445–76,084,735, 36 genes, copy number 27–58: AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5.
- chr12:76,351,797–77,065,569, 13 genes, copy number 17: OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7.
- chr12:90,107,739–90,300,974, 2 genes, copy number 45: AC126178.1, LINC02392.
- chr12:90,905,622–91,005,026, 3 genes, copy number 17–51 (within-gene range 2–51): CCER1, LINC00615, EPYC.
- chr12:92,420,094–92,772,455, 6 genes, copy number 27–55: CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7.
- chr12:96,101,951–96,269,824, 5 genes, copy number 31: RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2.
- chr12:96,303,375–96,303,513, 1 gene, copy number 31: RNU4-24P.
- chr12:97,939,056–97,939,121, 1 gene, copy number 21: MIR4495.
- chr12:101,568,353–101,696,450, 3 genes, copy number 41 (within-gene range 4–41): MYBPC1, AC117505.1, AC010205.1.
- chr12:107,685,799–107,720,133, 2 genes, copy number 7: PWP1, AC007622.1.
- chr12:110,910,819–112,418,838, 43 genes, copy number 11–31: MYL2, LINC01405, AC002351.1, CUX2, MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS, BRAP, PCNPP1, ACAD10, AC002996.1, ALDH2, MIR6761, MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2, NAA25, MIR3657, AC073575.1, Y_RNA, TRAFD1, Y_RNA, HECTD4, MIR6861, AC004217.1, RN7SKP71, RPL7AP60, AC004217.2, RPL6.
- chr12:117,453,012–117,968,990, 2 genes, copy number 12 (within-gene range 2–25): KSR2, AC084291.1.
- chr12:118,375,350–118,738,511, 6 genes, copy number 22: AC026367.1, SUDS3, AC026367.3, AC026367.2, LINC02460, RPL17P37.
- chr12:121,308,245–122,626,396, 43 genes, copy number 10–39 (within-gene range 2–39): ANAPC5, AC048337.1, RNF34, KDM2B, MIR7107, KDM2B-DT, RNU6-1004P, ORAI1, MORN3, AC084018.3, TMEM120B, RHOF, LINC01089, SETD1B, HPD, AC079360.1, AC069503.3, AC069503.5, PSMD9, AC069503.2, Metazoa_SRP, RNU7-170P, CFAP251, AC069503.1, BCL7A, AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A, CLIP1, RPL21P1, CLIP1-AS1, ZCCHC8, AC127002.1, AC127002.2, RSRC2, KNTC1, AC026333.1.
- chr12:126,094,112–126,191,406, 5 genes, copy number 33: LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1.
- chr12:131,620,178–131,668,246, 8 genes, copy number 19: AC117500.5, AC117500.3, LINC02414, AC117500.6, AC117500.4, RNA5SP377, AC117500.1, RPS6P21.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
